Somatic mutation profile of tumor specimen TCGA-43-7657-01A (aliquot TCGA-43-7657-01A-31D-2122-08) from TCGA case TCGA-43-7657, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 68.6 years (25,042 days).
Specimen TCGA-43-7657-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 04d17947-a470-4894-94c3-d6db8f02cbdd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-43-7657-10A (Blood Derived Normal), aliquot TCGA-43-7657-10A-01D-2122-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b64d3f2f-1608-452a-a503-bf884017547d

The open-access MAF lists 133 somatic variants for this specimen: 101 protein-altering or splice-affecting, 31 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 84, Silent 31, Frame Shift Del 5, Splice Site 5, Nonsense Mutation 5, Frame Shift Ins 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.97-9_97-2del p.X33_splice | Splice Site (DEL) | VAF 75/207 reads (36%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ADAMTS14 | c.1209-1G>T p.X403_splice | Splice Site (SNP) | VAF 16/63 reads (25%) | catalogued as COSV100941597; called by muse, mutect2, varscan2
- ALG13 | c.2979T>A p.Y993* | Nonsense Mutation (SNP) | VAF 10/41 reads (24%) | catalogued as COSV99322268; called by muse, mutect2, varscan2
- APBA1 | c.828G>T p.E276D | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.225); catalogued as COSV99596102; called by muse, mutect2, varscan2
- ARHGAP36 | c.1526G>A p.R509H | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs182540216, COSV52264298; called by muse, mutect2, varscan2
- ATXN2L | c.2264G>A p.R755H | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs546961698, COSV57374563; called by muse, mutect2, varscan2
- BCAP31 | c.481G>C p.A161P | Missense Mutation (SNP) | VAF 111/397 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.636); catalogued as COSV100798938; called by muse, mutect2, varscan2
- BRINP1 | c.1556G>A p.R519Q | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs912181785, COSV56292199; called by muse, mutect2, varscan2
- BRWD3 | c.3419C>A p.A1140D | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV100956075; called by muse, mutect2, varscan2
- C12orf40 | c.1711T>A p.C571S | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.045); catalogued as COSV100210104, COSV61134255; called by muse, mutect2, varscan2
- CA1 | c.161C>A p.P54Q | Missense Mutation (SNP) | VAF 41/304 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.938); catalogued as COSV99810164; called by muse, mutect2, varscan2
- CAMTA1 | c.2079G>T p.E693D | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.253); catalogued as COSV100349688; called by muse, mutect2, varscan2
- CCDC50 | c.394C>G p.P132A | Missense Mutation (SNP) | VAF 141/455 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as rs376944531, COSV66667521; called by muse, mutect2, varscan2
- CD207 | c.860A>G p.N287S | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs782253931, COSV101338564; called by muse, mutect2, varscan2
- CDH8 | c.958G>A p.G320R | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV100181625; called by muse, mutect2, varscan2
- CDK15 | c.1132G>A p.A378T (on ENST00000652192 / NM_001366386.2; = p.A327T on NM_139158.2) | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs144726331; called by muse, mutect2, varscan2
- CEP170 | c.800C>T p.T267M | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.661); catalogued as rs753597586, COSV100317099; called by muse, mutect2, varscan2
- CEP83 | c.11G>T p.S4I | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.361); catalogued as COSV100352858; called by muse, mutect2, varscan2
- CHST12 | c.1166G>A p.R389K | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.92); catalogued as COSV99324479; called by muse, mutect2, varscan2
- CILP | c.976G>A p.V326M | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs769257680, COSV56028788; called by muse, mutect2, varscan2
- CLIP2 | c.591G>T p.K197N | Missense Mutation (SNP) | VAF 51/126 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99791594; called by muse, mutect2, varscan2
- CYP2W1 | c.1429A>G p.M477V | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.98); PolyPhen benign (0.017); catalogued as COSV100417192; called by muse, mutect2, varscan2
- DACH1 | c.1400C>T p.A467V (on ENST00000619232 / NM_001366712.1; = p.A415V on NM_080759.6) | Missense Mutation (SNP) | VAF 80/124 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.829); catalogued as COSV100498375, COSV57509095; called by muse, mutect2, varscan2
- DIS3L2 | c.979G>C p.G327R | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99806320; called by muse, mutect2, varscan2
- DISC1 | c.1717A>G p.T573A | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.068); catalogued as COSV99697778; called by muse, mutect2
- EPB41L3 | c.2937C>A p.H979Q | Missense Mutation (SNP) | VAF 70/244 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV100549204; called by muse, mutect2, varscan2
- ERBB2 | c.1223-1G>T p.X408_splice | Splice Site (SNP) | VAF 54/96 reads (56%) | catalogued as COSV99507970; called by muse, mutect2, varscan2
- FAM3D | c.62T>C p.M21T | Missense Mutation (SNP) | VAF 53/142 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV100716823; called by muse, mutect2, varscan2
- FBXL16 | c.290C>A p.T97K | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0.039); catalogued as COSV100178981; called by muse, mutect2, varscan2
- FOXL2NB | c.422T>G p.L141R | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.051); catalogued as COSV100374558; called by muse, mutect2
- GNAS | c.214G>T p.G72C | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.981); catalogued as COSV99670081; called by muse, mutect2, varscan2
- GRAMD1C | c.1713G>T p.L571F | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100822820; called by muse, mutect2, varscan2
- GRM5 | c.1067A>C p.Q356P | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100552007; called by muse, mutect2, varscan2
- HMGB3 | c.265G>T p.D89Y | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV100308517; called by muse, mutect2, varscan2
- HNF4A | c.252C>A p.F84L | Missense Mutation (SNP) | VAF 40/66 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100291391, COSV57382660; called by muse, mutect2, varscan2
- HOXC8 | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99236841; called by muse, mutect2, varscan2
- HSPA1L | c.1567G>T p.D523Y | Missense Mutation (SNP) | VAF 50/360 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.853); catalogued as COSV100989492; called by muse, mutect2, varscan2
- HTATSF1 | c.1690G>C p.E564Q | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.197); catalogued as COSV99511659; called by muse, mutect2
- IKBIP | c.536T>C p.I179T | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as rs150453279; called by muse, mutect2, varscan2
- IL36B | c.238G>T p.G80C | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52086911, COSV99382761; called by muse, mutect2, varscan2
- KIAA1755 | c.1301C>A p.A434D | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.521); catalogued as COSV99642066; called by muse, mutect2, varscan2
- KIF16B | c.2786A>C p.E929A | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.321); catalogued as rs754150667, COSV100734310; called by muse, mutect2, varscan2
- LAMA4 | c.325C>A p.H109N | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.105); catalogued as COSV100038409; called by muse, mutect2, varscan2
- LHFPL5 | c.368C>G p.T123R | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.246); catalogued as COSV100798975; called by muse, mutect2, varscan2
- LPAR4 | c.385C>T p.L129F | Missense Mutation (SNP) | VAF 34/180 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70912246; called by muse, mutect2, varscan2
- LRRCC1 | c.721-2A>G p.X241_splice | Splice Site (SNP) | VAF 42/110 reads (38%) | catalogued as COSV100835454; called by muse, mutect2, varscan2
- MAGEB6 | c.182C>A p.P61H | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV100983661, COSV100983745; called by muse, mutect2, varscan2
- MASTL | c.2188G>C p.V730L (on ENST00000375940 / NM_001372029.1; = p.V729L on NM_032844.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/280 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV100668888; called by muse, mutect2, varscan2
- MED15 | c.568C>T p.Q190* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as COSV99487694; called by mutect2, varscan2
- MMS22L | c.85T>C p.F29L | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99246824; called by muse, mutect2, varscan2
- MYH13 | c.1737C>G p.F579L | Missense Mutation (SNP) | VAF 72/129 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs771048728, COSV52820945, COSV99354078; called by muse, mutect2, varscan2
- NCL | c.1165+1G>C p.X389_splice | Splice Site (SNP) | VAF 12/84 reads (14%) | catalogued as COSV100502357; called by muse, mutect2, varscan2
- NDUFAF5 | c.970G>A p.A324T | Missense Mutation (SNP) | VAF 29/220 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.581); catalogued as rs142611230; called by muse, mutect2, varscan2
- NPAS3 | c.833T>G p.I278S (on ENST00000356141 / NM_001164749.2; = p.I246S on NM_022123.3) | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV100640233; called by muse, mutect2, varscan2
- OAS2 | c.1656G>C p.E552D | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.121); catalogued as COSV100660160; called by muse, mutect2, varscan2
- OPHN1 | c.1765A>G p.I589V | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.223); catalogued as COSV100830445; called by muse, mutect2, varscan2
- OR10AG1 | c.715G>T p.V239L | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as COSV100400092; called by muse, mutect2, varscan2
- OR10AG1 | c.124del p.I42Ffs*24 | Frame Shift Del (DEL) | VAF 30/138 reads (22%) | catalogued as COSV56635102; called by mutect2, pindel, varscan2
- OR10G8 | c.181C>A p.L61I | Missense Mutation (SNP) | VAF 19/206 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV70908413, COSV70908571; called by muse, mutect2
- OR12D2 | c.259C>T p.H87Y | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.212); catalogued as COSV101011289; called by muse, mutect2, varscan2
- OR2A14 | c.735C>A p.C245* | Nonsense Mutation (SNP) | VAF 123/311 reads (40%) | catalogued as COSV101376469; called by muse, mutect2, varscan2
- OR2Y1 | c.929C>A p.S310* | Nonsense Mutation (SNP) | VAF 56/247 reads (23%) | catalogued as COSV100322755; called by muse, mutect2, varscan2
- OR4C11 | c.582C>G p.N194K | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV100155340; called by muse, mutect2, varscan2
- PCDH11X | c.3643C>A p.Q1215K | Missense Mutation (SNP) | VAF 60/181 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); catalogued as COSV100011825; called by muse, mutect2, varscan2
- PCDHGA7 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.262); catalogued as COSV53937182; called by muse, mutect2, varscan2
- PLEKHH1 | c.235G>C p.V79L | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV100233121; called by muse, mutect2, varscan2
- PPP4R1 | c.478G>C p.E160Q (on ENST00000400556 / NM_001042388.3; = p.E143Q on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99553506; called by muse, mutect2, varscan2
- PSG11 | c.558C>A p.S186R | Missense Mutation (SNP) | VAF 84/436 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.068); catalogued as COSV60458242; called by muse, mutect2, varscan2
- RFPL1 | c.422C>G p.S141C | Missense Mutation (SNP) | VAF 63/196 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100585758; called by muse, mutect2, varscan2
- RFX6 | c.945C>A p.F315L | Missense Mutation (SNP) | VAF 50/148 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.205); catalogued as COSV100263746; called by muse, mutect2, varscan2
- RIMS2 | c.3221C>T p.P1074L (on ENST00000666250 / NM_001348490.2; = p.P882L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.972); catalogued as COSV99169678; called by muse, mutect2, varscan2
- RNF213 | c.5941A>T p.N1981Y | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV100300622; called by muse, mutect2, varscan2
- SI | c.5026G>T p.A1676S | Missense Mutation (SNP) | VAF 155/223 reads (70%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.465); catalogued as rs746239339, COSV100015603, COSV52284692; called by muse, mutect2, varscan2
- SLC25A14 | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99502459; called by muse, mutect2, varscan2
- SLC26A5 | c.1852C>G p.P618A | Missense Mutation (SNP) | VAF 19/174 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.012); catalogued as COSV100099319; called by muse, mutect2, varscan2
- SLCO1C1 | c.1111G>A p.G371S | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1364933586, COSV56879074; called by muse, mutect2, varscan2
- STAB2 | c.3191T>C p.M1064T | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs370711917; called by muse, mutect2, varscan2
- TACC1 | c.854A>G p.Q285R | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.523); catalogued as rs147707491; called by muse, mutect2, varscan2
- TBR1 | c.1289C>G p.S430C | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV101271472; called by muse, mutect2, varscan2
- TCP11L2 | c.1375A>G p.M459V | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs757062673, COSV100135348; called by muse, mutect2, varscan2
- TEX47 | c.245G>T p.G82V | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as COSV51879469, COSV99787290; called by muse, mutect2, varscan2
- TLE1 | c.1912A>C p.N638H | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as COSV100918901; called by muse, mutect2, varscan2
- TMEM185A | c.46C>A p.L16I | Missense Mutation (SNP) | VAF 54/178 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.158); catalogued as COSV100383060; called by muse, mutect2, varscan2
- TMEM81 | c.391G>T p.D131Y | Missense Mutation (SNP) | VAF 61/125 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV99196811; called by muse, mutect2, varscan2
- TNFRSF19 | c.122A>T p.D41V | Missense Mutation (SNP) | VAF 95/165 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV99947393; called by muse, mutect2, varscan2
- TTN | c.27148C>A p.L9050I (on ENST00000591111; = p.L8123I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/112 reads (38%) | PolyPhen benign (0.098); catalogued as COSV100613681; called by muse, mutect2, varscan2
- TXNDC16 | c.751C>G p.L251V | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as COSV55987583, COSV99909238; called by muse, mutect2, varscan2
- UFL1 | c.2116G>T p.G706* | Nonsense Mutation (SNP) | VAF 20/50 reads (40%) | catalogued as COSV100990070; called by muse, mutect2, varscan2
- XK | c.267C>G p.I89M | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.91); catalogued as COSV101064675; called by muse, mutect2
- XRN1 | c.4276G>A p.D1426N | Missense Mutation (SNP) | VAF 12/230 reads (5%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.051); catalogued as rs1295740744, COSV99378017; called by muse, mutect2
- ZFHX3 | c.3781C>T p.L1261F | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.973); catalogued as COSV99196853, COSV99212430; called by muse, mutect2, varscan2
- ZNF423 | c.2495A>T p.K832M (on ENST00000563137 / NM_001379286.1; = p.K824M on NM_015069.4) | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV99281736; called by muse, mutect2, varscan2
- ZNF558 | c.922A>T p.T308S | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.399); catalogued as COSV100037939; called by muse, mutect2, varscan2
- ZNF75D | c.422A>T p.H141L | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.459); catalogued as COSV100883643; called by muse, mutect2, varscan2
- ARMCX1 | c.653del p.N218Mfs*8 | Frame Shift Del (DEL) | VAF 90/329 reads (27%) | called by mutect2, pindel, varscan2
- CCR2 | c.287del p.P96Hfs*39 | Frame Shift Del (DEL) | VAF 87/246 reads (35%) | called by mutect2, pindel, varscan2
- DPH5 | c.824del p.N275Ifs*53 | Frame Shift Del (DEL) | VAF 30/128 reads (23%) | called by mutect2, pindel, varscan2
- FOSB | c.932_935dup p.A313Lfs*13 | Frame Shift Ins (INS) | VAF 11/89 reads (12%) | called by mutect2, pindel, varscan2
- LEMD3 | c.2407C>T p.H803Y | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.097); called by muse, mutect2
- SALL1 | c.242del p.P81Hfs*18 | Frame Shift Del (DEL) | VAF 18/105 reads (17%) | called by mutect2, pindel, varscan2
- TXNDC2 | c.765dup p.K256Qfs*28 (on ENST00000306084 / NM_001098529.2; = p.K189Qfs*28 on NM_032243.6) | Frame Shift Ins (INS) | VAF 38/234 reads (16%) | called by mutect2, pindel, varscan2
- ASIC5 | c.615A>T p.G205= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as COSV101539748; called by muse, mutect2, varscan2
- BCHE | c.933G>A p.G311= | Silent (SNP) | VAF 18/214 reads (8%) | catalogued as COSV100012554; called by muse, mutect2
- CDYL2 | c.354A>G p.K118= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as COSV101629564; called by muse, mutect2, varscan2
- CENPI | c.753A>T p.S251= | Silent (SNP) | VAF 82/494 reads (17%) | catalogued as COSV99515409; called by muse, mutect2, varscan2
- COL27A1 | c.1518G>A p.T506= | Silent (SNP) | VAF 85/205 reads (41%) | catalogued as rs139976325, COSV61924344; called by muse, mutect2, varscan2
- CPSF1 | c.798C>G p.T266= | Silent (SNP) | VAF 27/132 reads (20%) | catalogued as COSV100574464; called by muse, mutect2, varscan2
- DDC | c.48C>T p.Y16= | Silent (SNP) | VAF 112/315 reads (36%) | catalogued as rs745576871, COSV63564632; called by muse, mutect2, varscan2
- DLGAP1 | c.345C>T p.R115= | Silent (SNP) | VAF 34/109 reads (31%) | catalogued as rs777255082, COSV59816294; called by muse, mutect2, varscan2
- EGFLAM | c.930C>T p.P310= | Silent (SNP) | VAF 30/291 reads (10%) | catalogued as COSV100380301; called by muse, mutect2, varscan2
- EIF4G3 | c.417A>G p.K139= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV99944299; called by muse, mutect2, varscan2
- FAM71B | c.354G>A p.E118= | Silent (SNP) | VAF 43/78 reads (55%) | catalogued as rs764804273, COSV100262117; called by muse, mutect2, varscan2
- FRG2 | c.651G>T p.L217= | Silent (SNP) | VAF 11/52 reads (21%) | called by muse, mutect2, varscan2
- FSHR | c.1246C>T p.L416= | Silent (SNP) | VAF 23/133 reads (17%) | catalogued as COSV100437203; called by muse, mutect2, varscan2
- HDAC8 | c.264T>C p.D88= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as COSV101002370; called by muse, mutect2, varscan2
- HTR1F | c.498T>C p.T166= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as COSV100138092; called by muse, mutect2, varscan2
- IFIT1B | c.1287T>C p.C429= | Silent (SNP) | VAF 88/248 reads (35%) | catalogued as rs371267850; called by muse, mutect2, varscan2
- ITGB7 | c.2127G>A p.T709= | Silent (SNP) | VAF 41/122 reads (34%) | catalogued as rs768198931, COSV99914081; called by muse, mutect2, varscan2
- MAGEA10 | c.708A>C p.I236= | Silent (SNP) | VAF 31/115 reads (27%) | catalogued as COSV99726727; called by muse, mutect2, varscan2
- NCOA1 | c.1209A>G p.S403= | Silent (SNP) | VAF 32/79 reads (41%) | catalogued as COSV99946094; called by muse, mutect2, varscan2
- PCDH1 | c.2256G>C p.L752= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as COSV99746226; called by muse, mutect2, varscan2
- PCOLCE | c.862C>A p.R288= | Silent (SNP) | VAF 18/91 reads (20%) | catalogued as COSV56159893, COSV99775234; called by muse, mutect2, varscan2
- PPP1R3F | c.1176A>C p.A392= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV99278744; called by muse, mutect2, varscan2
- PROSER2 | c.456C>A p.P152= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV53204126; called by muse, mutect2, varscan2
- RAB40A | c.42G>C p.L14= | Silent (SNP) | VAF 32/135 reads (24%) | catalogued as COSV100420930; called by muse, mutect2, varscan2
- RASGEF1A | c.1329G>A p.A443= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as rs969218814, COSV100988621; called by muse, mutect2, varscan2
- RTEL1 | c.1623G>A p.L541= | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as rs1201390599, COSV100542300; called by muse, mutect2
- RTL1 | c.2869C>T p.L957= | Silent (SNP) | VAF 58/142 reads (41%) | catalogued as rs1386728027, COSV101128295; called by muse, mutect2, varscan2
- SYNE1 | c.21309A>C p.T7103= (on ENST00000367255 / NM_182961.4; = p.T7032= on NM_033071.3) | Silent (SNP) | VAF 22/153 reads (14%) | catalogued as COSV99564837; called by muse, mutect2, varscan2
- TIAM2 | c.1278A>G p.A426= | Silent (SNP) | VAF 35/105 reads (33%) | catalogued as rs757624118, COSV100019131; called by muse, mutect2, varscan2
- ZNF331 | c.813C>T p.Y271= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as rs201448146, COSV53479537; called by muse, mutect2, varscan2
- ZNF438 | c.2316C>A p.S772= | Silent (SNP) | VAF 9/230 reads (4%) | catalogued as COSV100061946; called by muse, mutect2
- MAGEB1 | c.*1G>T | 3'UTR (SNP) | VAF 9/81 reads (11%) | catalogued as COSV100974976; called by muse, mutect2, varscan2
